Somatic mutation profile of cancer-model specimen HCM-WCMC-0788-C34-85A (3D Organoid, passage 12; aliquot HCM-WCMC-0788-C34-85A-01D-A87L-36), derived from the primary tumor of HCMI case HCM-WCMC-0788-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Solid carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 72.6 years (26,516 days).
Specimen HCM-WCMC-0788-C34-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Cryopreserved; Passage count: 12.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a31774ca-3814-4d61-9eb3-8809f0c0dbc6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0788-C34-10A (Blood Derived Normal), aliquot HCM-WCMC-0788-C34-10A-01D-A87L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b83daa83-a15e-4e01-987d-ecda52219de4

The open-access MAF lists 663 somatic variants for this specimen: 515 protein-altering or splice-affecting, 120 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 443, Silent 120, Nonsense Mutation 39, Intron 14, Frame Shift Del 11, Splice Region 9, 3'UTR 4, In Frame Del 4, Splice Site 4, RNA 4, Frame Shift Ins 3, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.2041C>T p.R681* | Nonsense Mutation (SNP) | VAF 237/237 reads (100%) | catalogued as rs768638173, CM000025, COSV62223641; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 189/190 reads (99%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs587780073, CM035576, COSV52661201, COSV52686167, COSV53142556; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AATK | c.1823G>A p.R608H (on ENST00000326724 / NM_001080395.3; = p.R505H on NM_004920.2) | Missense Mutation (SNP) | VAF 133/764 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs756473019; called by muse, mutect2, varscan2
- ABCG1 | c.647G>A p.S216N | Missense Mutation (SNP) | VAF 279/668 reads (42%) | SIFT tolerated (0.81); PolyPhen benign (0.014); catalogued as rs761202119; called by muse, mutect2, varscan2
- ABCG8 | c.361C>T p.R121* | Nonsense Mutation (SNP) | VAF 69/355 reads (19%) | catalogued as rs375005392, CM012309; called by muse, mutect2, varscan2
- AC136428.1 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 245/767 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.91); catalogued as rs766270124, COSV101434973; called by muse, mutect2, varscan2
- ACTN2 | c.1058G>T p.R353L | Missense Mutation (SNP) | VAF 162/527 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV100857076; called by muse, mutect2, varscan2
- ADAMTS2 | c.3562G>T p.E1188* | Nonsense Mutation (SNP) | VAF 130/351 reads (37%) | catalogued as rs768095088; called by muse, mutect2, varscan2
- ADAMTS3 | c.232G>T p.E78* | Nonsense Mutation (SNP) | VAF 98/445 reads (22%) | catalogued as COSV99710500; called by muse, mutect2, varscan2
- ADCY8 | c.2540G>T p.C847F | Missense Mutation (SNP) | VAF 143/618 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53923632; called by muse, mutect2, varscan2
- ADCY8 | c.787G>T p.G263C | Missense Mutation (SNP) | VAF 86/819 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.788); catalogued as COSV53932785; called by muse, mutect2, varscan2
- ADGRD2 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 112/335 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.028); catalogued as rs1218965756, COSV58340273; called by muse, mutect2, varscan2
- ADGRF1 | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 98/616 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100982672, COSV64799978; called by muse, mutect2, varscan2
- ADGRG4 | c.5389A>T p.K1797* | Nonsense Mutation (SNP) | VAF 337/338 reads (100%) | catalogued as COSV54956098; called by muse, mutect2, varscan2
- AGO2 | c.1631C>T p.T544M | Missense Mutation (SNP) | VAF 100/777 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1382352330; called by muse, mutect2, varscan2
- AHNAK | c.14517G>T p.M4839I | Missense Mutation (SNP) | VAF 407/520 reads (78%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); catalogued as COSV57219269; called by muse, mutect2, varscan2
- AMER1 | c.1441G>T p.D481Y | Missense Mutation (SNP) | VAF 462/462 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV57658429; called by muse, mutect2, varscan2
- ANKLE2 | c.1689G>T p.E563D | Missense Mutation (SNP) | VAF 72/326 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV61709683; called by muse, mutect2, varscan2
- APBA2 | c.2052G>A p.M684I | Missense Mutation (SNP) | VAF 200/669 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV68790993; called by muse, mutect2, varscan2
- ARMC2 | c.2356T>C p.W786R | Missense Mutation (SNP) | VAF 44/524 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100933575; called by muse, mutect2
- ASNSD1 | c.37G>C p.E13Q | Missense Mutation (SNP) | VAF 207/382 reads (54%) | SIFT tolerated (0.77); PolyPhen benign (0.006); catalogued as rs769391454, COSV53622907; called by muse, mutect2, varscan2
- ASXL3 | c.976G>T p.G326* | Nonsense Mutation (SNP) | VAF 53/241 reads (22%) | catalogued as COSV52463849; called by muse, mutect2, varscan2
- ATRX | c.1630C>T p.H544Y | Missense Mutation (SNP) | VAF 147/308 reads (48%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV64883000, COSV64887319; called by muse, mutect2, varscan2
- AWAT1 | c.258C>A p.I86= | Splice Region (SNP) | VAF 326/326 reads (100%) | catalogued as rs372598538; called by muse, mutect2, varscan2
- BCL6B | c.1265G>A p.R422H | Missense Mutation (SNP) | VAF 160/420 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1350301685; called by muse, mutect2, varscan2
- BNC1 | c.2561C>G p.T854S | Missense Mutation (SNP) | VAF 197/323 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.112); catalogued as COSV100596933; called by muse, mutect2, varscan2
- BRINP1 | c.58G>T p.V20L | Missense Mutation (SNP) | VAF 115/291 reads (40%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.043); catalogued as COSV99776688; called by muse, mutect2, varscan2
- C9orf153 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 62/184 reads (34%) | SIFT tolerated (0.89); PolyPhen benign (0.007); catalogued as rs757025356; called by muse, mutect2, varscan2
- CA6 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 37/286 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0.01); catalogued as rs533616544, COSV66262258, COSV66263535; called by muse, mutect2, varscan2
- CACNA1E | c.2203G>T p.V735F | Missense Mutation (SNP) | VAF 52/288 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as rs528168265, COSV62395483; called by muse, mutect2, varscan2
- CACNA1E | c.6708C>A p.H2236Q (on ENST00000367573 / NM_001205293.3; = p.H2193Q on NM_000721.4) | Missense Mutation (SNP) | VAF 121/613 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as COSV62415033; called by muse, mutect2, varscan2
- CADPS | c.3946G>A p.E1316K | Missense Mutation (SNP) | VAF 77/345 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.108); catalogued as COSV51874730; called by muse, mutect2, varscan2
- CCT6B | c.985G>T p.G329C | Missense Mutation (SNP) | VAF 108/377 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100031061; called by muse, mutect2, varscan2
- CDKL2 | c.1228G>T p.V410L | Missense Mutation (SNP) | VAF 327/446 reads (73%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as rs150511430, COSV99048749; called by muse, mutect2, varscan2
- CLEC20A | c.33C>A p.C11* | Nonsense Mutation (SNP) | VAF 194/593 reads (33%) | catalogued as rs1048187920; called by muse, mutect2, varscan2
- CLK1 | c.44A>G p.K15R | Missense Mutation (SNP) | VAF 268/438 reads (61%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs749539322; called by muse, mutect2, varscan2
- CLMN | c.312G>T p.L104F | Missense Mutation (SNP) | VAF 225/529 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100112594; called by muse, mutect2, varscan2
- CNTNAP2 | c.1609G>T p.A537S | Missense Mutation (SNP) | VAF 172/302 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs757574876, COSV62159605, COSV62222788, COSV62222789; called by muse, mutect2, varscan2
- COL25A1 | c.1472G>A p.G491D | Missense Mutation (SNP) | VAF 142/308 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs889707262; called by muse, mutect2, varscan2
- COL4A3 | c.3062G>T p.G1021V | Missense Mutation (SNP) | VAF 142/375 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59259749; called by muse, mutect2, varscan2
- COL5A2 | c.1447G>T p.G483W | Missense Mutation (SNP) | VAF 145/284 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66411245; called by muse, mutect2, varscan2
- COMP | c.1790C>A p.A597E | Missense Mutation (SNP) | VAF 281/281 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1224528574; called by muse, mutect2, varscan2
- DCHS1 | c.9707G>T p.R3236L | Missense Mutation (SNP) | VAF 242/535 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV54996730; called by muse, mutect2, varscan2
- DDX3X | c.682G>T p.G228* (on ENST00000399959; = p.G229* on NM_001356.5) | Nonsense Mutation (SNP) | VAF 79/79 reads (100%) | catalogued as COSV101302547, COSV67864369; called by muse, mutect2, varscan2
- DMRTB1 | c.326C>A p.P109Q | Missense Mutation (SNP) | VAF 72/488 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.099); catalogued as rs1312443670; called by muse, mutect2, varscan2
- DPYS | c.1090G>T p.V364L | Missense Mutation (SNP) | VAF 276/563 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138282507, CM102075; called by muse, mutect2, varscan2
- DRD2 | c.1137C>A p.L379= | Splice Region (SNP) | VAF 53/239 reads (22%) | catalogued as COSV60763426; called by muse, mutect2, varscan2
- EGLN3 | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 260/260 reads (100%) | SIFT tolerated (0.09); PolyPhen benign (0.065); catalogued as rs375310922; called by muse, mutect2, varscan2
- ELAVL3 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 78/227 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); catalogued as rs747316633, COSV63645512; called by muse, mutect2, varscan2
- EML3 | c.500G>C p.R167P | Missense Mutation (SNP) | VAF 107/470 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.579); catalogued as rs768136249, COSV99606027; called by muse, mutect2, varscan2
- EPHA5 | c.427G>T p.G143* | Nonsense Mutation (SNP) | VAF 260/329 reads (79%) | catalogued as COSV56655170; called by muse, mutect2, varscan2
- EPN2 | c.1036C>G p.P346A | Missense Mutation (SNP) | VAF 220/618 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs760514767; called by muse, mutect2, varscan2
- ERICH3 | c.3930G>T p.Q1310H | Missense Mutation (SNP) | VAF 120/583 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.181); catalogued as COSV100446181; called by muse, mutect2, varscan2
- ETFBKMT | c.298G>A p.G100S | Missense Mutation (SNP) | VAF 148/229 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371728423; called by muse, mutect2, varscan2
- EXOC8 | c.185A>G p.N62S | Missense Mutation (SNP) | VAF 129/786 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1267504772; called by muse, mutect2, varscan2
- EYS | c.1107C>A p.S369R | Missense Mutation (SNP) | VAF 174/198 reads (88%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV61000228; called by muse, mutect2
- FAM160A1 | c.2977C>A p.P993T | Missense Mutation (SNP) | VAF 116/462 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1411229778; called by mutect2, varscan2
- FLG2 | c.2849A>C p.Q950P | Missense Mutation (SNP) | VAF 257/430 reads (60%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.72); catalogued as rs1288308098, COSV101166091; called by muse, mutect2, varscan2
- FOXG1 | c.1171G>T p.G391C | Missense Mutation (SNP) | VAF 253/555 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV57394865; called by muse, mutect2, varscan2
- FOXG1 | c.1172G>T p.G391V | Missense Mutation (SNP) | VAF 256/557 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1471936774; called by muse, mutect2, varscan2
- GABBR2 | c.412G>A p.V138I | Missense Mutation (SNP) | VAF 107/390 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs760685140, COSV52300397; called by muse, mutect2, varscan2
- GABRB3 | c.416G>T p.R139L | Missense Mutation (SNP) | VAF 77/543 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV54661471, COSV54667048; called by muse, mutect2, varscan2
- GALNT5 | c.331G>C p.E111Q | Missense Mutation (SNP) | VAF 201/356 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV52036370; called by muse, mutect2, varscan2
- GATM | c.1000G>A p.G334R | Missense Mutation (SNP) | VAF 112/169 reads (66%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs749007953; called by muse, mutect2, varscan2
- GPRC5B | c.74C>T p.S25L | Missense Mutation (SNP) | VAF 84/310 reads (27%) | SIFT tolerated (0.59); PolyPhen benign (0.041); catalogued as rs1411388555; called by muse, mutect2, varscan2
- GRIA3 | c.1886C>A p.S629Y | Missense Mutation (SNP) | VAF 136/257 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52080739; called by muse, mutect2, varscan2
- GRIPAP1 | c.1397G>A p.R466H | Missense Mutation (SNP) | VAF 221/222 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1284469158, COSV64551985; called by muse, mutect2, varscan2
- HCLS1 | c.1274G>C p.G425A | Missense Mutation (SNP) | VAF 116/474 reads (24%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.794); catalogued as COSV57523771; called by muse, mutect2, varscan2
- HERC2 | c.13202G>T p.R4401L | Missense Mutation (SNP) | VAF 212/542 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55309383; called by muse, mutect2, varscan2
- HRNR | c.381T>G p.F127L | Missense Mutation (SNP) | VAF 174/445 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV64263737; called by muse, mutect2, varscan2
- HSF5 | c.77G>C p.R26P | Missense Mutation (SNP) | VAF 160/452 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV100051270, COSV60201683; called by muse, mutect2, varscan2
- IFFO2 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 93/372 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1443004685, COSV69086375; called by muse, mutect2, varscan2
- IFNAR1 | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 50/216 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as rs201609461; called by muse, mutect2, varscan2
- IGHV1-2 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 88/587 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.165); catalogued as rs782446988; called by muse, mutect2, varscan2
- IGSF9 | c.1883G>T p.R628L (on ENST00000368094 / NM_001135050.2; = p.R612L on NM_020789.4) | Missense Mutation (SNP) | VAF 123/708 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.262); catalogued as rs928432972, COSV100829632; called by muse, mutect2, varscan2
- IKZF4 | c.376G>A p.V126M | Missense Mutation (SNP) | VAF 84/620 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.162); catalogued as rs780345169, COSV56270364; called by muse, mutect2, varscan2
- KIAA1614 | c.3412C>T p.R1138C | Missense Mutation (SNP) | VAF 64/809 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs763116496; called by muse, mutect2
- KLK5 | c.741del p.P248Lfs*65 | Frame Shift Del (DEL) | VAF 245/516 reads (47%) | catalogued as rs759781166; called by mutect2, pindel, varscan2
- KPRP | c.602G>C p.C201S | Missense Mutation (SNP) | VAF 195/553 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV100908644; called by muse, mutect2, varscan2
- KRT75 | c.1643G>C p.S548T | Missense Mutation (SNP) | VAF 189/324 reads (58%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as COSV52872913; called by muse, mutect2, varscan2
- KTI12 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 229/440 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs750477587; called by muse, mutect2, varscan2
- L1TD1 | c.1547G>T p.G516V | Missense Mutation (SNP) | VAF 98/409 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.242); catalogued as COSV63134301; called by muse, mutect2, varscan2
- LBP | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 65/434 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.06); catalogued as rs770900154; called by muse, mutect2, varscan2
- LDB3 | c.1631C>A p.A544D | Missense Mutation (SNP) | VAF 35/416 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as rs1265432173, COSV99555007; called by muse, mutect2
- LMAN1L | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 20/291 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1366395705, COSV100547722, COSV59003215; called by muse, mutect2
- LPA | c.2815G>T p.E939* | Nonsense Mutation (SNP) | VAF 130/141 reads (92%) | catalogued as COSV100308119; called by muse, varscan2
- MAGEA4 | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 297/297 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52342551; called by muse, mutect2, varscan2
- MED24 | c.404C>T p.T135M | Missense Mutation (SNP) | VAF 87/450 reads (19%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.782); catalogued as rs779932815, COSV62418522; called by muse, mutect2, varscan2
- MGAM | c.5240G>T p.G1747V | Missense Mutation (SNP) | VAF 287/496 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV101527382, COSV72075476; called by muse, mutect2, varscan2
- MMP16 | c.437C>A p.P146H | Missense Mutation (SNP) | VAF 134/623 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV54171969; called by muse, mutect2, varscan2
- MOXD1 | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 407/441 reads (92%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV63452444; called by muse, mutect2, varscan2
- MPEG1 | c.742G>A p.V248M | Missense Mutation (SNP) | VAF 73/434 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as rs551823490, COSV57090064; called by muse, mutect2, varscan2
- MPPED2 | c.421G>T p.V141L | Missense Mutation (SNP) | VAF 101/436 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0.031); catalogued as COSV63896195; called by muse, mutect2, varscan2
- MROH1 | c.3571G>A p.V1191M | Missense Mutation (SNP) | VAF 274/665 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); catalogued as rs983052182; called by muse, mutect2, varscan2
- MRPL22 | c.313A>C p.K105Q | Missense Mutation (SNP) | VAF 65/207 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs200195885; called by muse, mutect2, varscan2
- MS4A2 | c.360G>T p.R120S | Missense Mutation (SNP) | VAF 49/339 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV54014400; called by muse, mutect2, varscan2
- MT1H | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 138/245 reads (56%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as COSV60090520; called by muse, mutect2, varscan2
- MUC5B | c.1223C>A p.T408N | Missense Mutation (SNP) | VAF 133/280 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs750488803; called by muse, mutect2, varscan2
- MXRA5 | c.7999G>T p.G2667* | Nonsense Mutation (SNP) | VAF 120/121 reads (99%) | catalogued as COSV54235133; called by muse, mutect2, varscan2
- MXRA5 | c.6991G>T p.G2331W | Missense Mutation (SNP) | VAF 143/144 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54239645; called by muse, mutect2, varscan2
- MYLK | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 83/358 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0.086); catalogued as rs367649461; called by muse, mutect2, varscan2
- NAT1 | c.590G>T p.R197L | Missense Mutation (SNP) | VAF 124/257 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.489); catalogued as COSV100306502; called by muse, mutect2, varscan2
- NEB | c.1849G>T p.D617Y | Missense Mutation (SNP) | VAF 104/282 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50808237; called by muse, mutect2, varscan2
- NETO1 | c.131G>T p.W44L | Missense Mutation (SNP) | VAF 87/364 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.267); catalogued as COSV55003147; called by muse, mutect2, varscan2
- NMUR2 | c.450C>G p.H150Q | Missense Mutation (SNP) | VAF 112/325 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV54921052; called by muse, mutect2, varscan2
- NRXN1 | c.2065G>A p.G689S | Missense Mutation (SNP) | VAF 100/480 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV100457073; called by muse, mutect2, varscan2
- NRXN3 | c.664C>T p.R222C (on ENST00000557594 / NM_001272020.2; = p.R854C on NM_004796.6) | Missense Mutation (SNP) | VAF 180/293 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs747277637, COSV55315618; called by muse, mutect2, varscan2
- NWD2 | c.1871G>C p.R624T | Missense Mutation (SNP) | VAF 28/597 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.261); catalogued as COSV58749090; called by muse, mutect2
- OLFM1 | c.922G>T p.G308C (on ENST00000371793 / NM_001282611.2; = p.G290C on NM_014279.5) | Missense Mutation (SNP) | VAF 98/328 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99423214; called by muse, mutect2, varscan2
- OPLAH | c.2347G>T p.V783L | Missense Mutation (SNP) | VAF 371/883 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as rs1554758672; called by muse, mutect2, varscan2
- OR10S1 | c.337G>T p.V113L | Missense Mutation (SNP) | VAF 285/285 reads (100%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs775734563, COSV73342735; called by muse, mutect2, varscan2
- OR2B11 | c.260T>A p.V87D | Missense Mutation (SNP) | VAF 163/503 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV59509846; called by muse, mutect2, varscan2
- OR2T2 | c.435G>T p.M145I | Missense Mutation (SNP) | VAF 131/726 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.168); catalogued as rs747466637, COSV100737801; called by muse, mutect2, varscan2
- OR2W3 | c.634G>A p.V212M | Missense Mutation (SNP) | VAF 220/458 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as rs1388972305; called by muse, mutect2, varscan2
- OR4A15 | c.705C>G p.F235L | Missense Mutation (SNP) | VAF 166/446 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV59036503; called by muse, mutect2, varscan2
- OR6K2 | c.229A>T p.T77S | Missense Mutation (SNP) | VAF 112/354 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs763659944; called by muse, mutect2, varscan2
- PAPPA2 | c.1320C>A p.H440Q | Missense Mutation (SNP) | VAF 161/456 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs763446637; called by muse, mutect2, varscan2
- PCDH10 | c.1787C>A p.P596Q | Missense Mutation (SNP) | VAF 126/591 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52092050; called by muse, mutect2, varscan2
- PCDH15 | c.2316C>A p.Y772* | Nonsense Mutation (SNP) | VAF 92/336 reads (27%) | catalogued as COSV57412543; called by muse, mutect2, varscan2
- PCDHA10 | c.1688C>A p.A563E | Missense Mutation (SNP) | VAF 375/375 reads (100%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.04); catalogued as rs1554150585, COSV100252212, COSV56491089; called by muse, mutect2, varscan2
- PDZRN3 | c.1939C>T p.R647C | Missense Mutation (SNP) | VAF 98/447 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs746378403, COSV55193847, COSV55195895, COSV55201867; called by muse, mutect2, varscan2
- PIK3CG | c.2275G>A p.V759I | Missense Mutation (SNP) | VAF 97/317 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs765080806, COSV63245292; called by muse, mutect2, varscan2
- PLA2G5 | c.218G>T p.R73L | Missense Mutation (SNP) | VAF 51/339 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs373547855; called by muse, mutect2, varscan2
- PLXNC1 | c.3640G>A p.A1214T | Missense Mutation (SNP) | VAF 127/415 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as rs368088029; called by muse, mutect2, varscan2
- PROX1 | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 59/515 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.192); catalogued as COSV54778426; called by muse, mutect2, varscan2
- PRPF3 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 194/463 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV100254773, COSV61396165; called by muse, mutect2, varscan2
- PYHIN1 | c.703C>A p.Q235K | Missense Mutation (SNP) | VAF 53/371 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100932334, COSV100932348; called by muse, mutect2, varscan2
- RAX2 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 152/473 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs941526473; called by muse, mutect2, varscan2
- REEP4 | c.388G>T p.A130S | Missense Mutation (SNP) | VAF 159/299 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.706); catalogued as rs770498333; called by muse, mutect2, varscan2
- RGSL1 | c.2851A>G p.I951V | Missense Mutation (SNP) | VAF 154/384 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0.018); catalogued as rs1182688990; called by muse, mutect2, varscan2
- SBNO2 | c.1235C>T p.P412L | Missense Mutation (SNP) | VAF 327/329 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1446324272; called by muse, mutect2, varscan2
- SCN2A | c.1729C>A p.L577I | Missense Mutation (SNP) | VAF 128/319 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs796053187, COSV51855359; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN8A | c.269C>T p.T90M | Missense Mutation (SNP) | VAF 188/322 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as rs763078635; called by muse, mutect2, varscan2
- SEMA5A | c.2027G>T p.R676L | Missense Mutation (SNP) | VAF 187/727 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66799890; called by muse, mutect2, varscan2
- SEMA5A | c.1592C>T p.A531V | Missense Mutation (SNP) | VAF 145/527 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs202102793, COSV66795676; called by muse, mutect2, varscan2
- SERPINA5 | c.421C>A p.L141M | Missense Mutation (SNP) | VAF 363/731 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.287); catalogued as COSV61574307; called by muse, mutect2
- SETD3 | c.1523G>A p.G508E | Missense Mutation (SNP) | VAF 204/683 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as COSV100074987; called by muse, mutect2, varscan2
- SHANK1 | c.382G>T p.D128Y | Missense Mutation (SNP) | VAF 220/578 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99521565; called by muse, mutect2, varscan2
- SLC38A10 | c.580G>A p.V194I | Missense Mutation (SNP) | VAF 150/658 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0.101); catalogued as rs755525430, COSV99917988; called by muse, mutect2, varscan2
- SLITRK3 | c.1567G>T p.A523S | Missense Mutation (SNP) | VAF 284/563 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as COSV53847696, COSV53847840; called by muse, mutect2, varscan2
- SREBF1 | c.3344C>T p.A1115V | Missense Mutation (SNP) | VAF 247/693 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768240923, COSV55399928; called by muse, mutect2, varscan2
- ST18 | c.2259G>C p.K753N | Missense Mutation (SNP) | VAF 239/579 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52485410; called by muse, mutect2, varscan2
- STAB2 | c.3775C>A p.H1259N | Missense Mutation (SNP) | VAF 158/469 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV104429580; called by muse, mutect2, varscan2
- STK38 | c.1331C>T p.T444M | Missense Mutation (SNP) | VAF 87/490 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs757931650, COSV57707921; called by muse, mutect2, varscan2
- SVEP1 | c.9854G>T p.R3285I | Missense Mutation (SNP) | VAF 142/231 reads (61%) | SIFT tolerated (0.08); PolyPhen benign (0.399); catalogued as rs370695796, COSV52837509; called by muse, mutect2, varscan2
- SVOP | c.1195C>T p.R399C | Missense Mutation (SNP) | VAF 32/323 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1289801633, COSV54464522; called by muse, mutect2, varscan2
- SZT2 | c.8327C>A p.P2776H (on ENST00000634258 / NM_001365999.1; = p.P2719H on NM_015284.4) | Missense Mutation (SNP) | VAF 220/527 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV100987307; called by muse, mutect2, varscan2
- TACC2 | c.4841G>T p.G1614V | Missense Mutation (SNP) | VAF 75/298 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs150804431; called by muse, mutect2, varscan2
- TBC1D25 | c.1008C>G p.D336E | Missense Mutation (SNP) | VAF 148/238 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100952100; called by muse, mutect2, varscan2
- TBX3 | c.1480G>T p.A494S (on ENST00000257566 / NM_016569.4; = p.A474S on NM_005996.4) | Missense Mutation (SNP) | VAF 411/695 reads (59%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57471303; called by muse, mutect2, varscan2
- TLL1 | c.341G>A p.R114K | Missense Mutation (SNP) | VAF 48/276 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.068); catalogued as COSV50267744; called by muse, mutect2, varscan2
- TMEM200A | c.238G>T p.V80F | Missense Mutation (SNP) | VAF 38/394 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV51653964; called by muse, mutect2
- TMX3 | c.349C>T p.R117* | Nonsense Mutation (SNP) | VAF 29/209 reads (14%) | catalogued as rs376484673; called by muse, mutect2, varscan2
- TNN | c.521C>A p.A174E | Missense Mutation (SNP) | VAF 221/644 reads (34%) | SIFT tolerated (1); PolyPhen possibly damaging (0.459); catalogued as rs200816440; called by muse, mutect2, varscan2
- TNS1 | c.1048A>G p.M350V | Missense Mutation (SNP) | VAF 234/429 reads (55%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as rs1164705617; called by muse, mutect2, varscan2
- TNXB | c.11267C>A p.P3756H (on ENST00000647633; = p.P3509H on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 193/609 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs961333651; called by muse, mutect2, varscan2
- TRIOBP | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 202/425 reads (48%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as rs760570250, COSV60378229; called by muse, mutect2, varscan2
- TRPM1 | c.667G>T p.E223* | Nonsense Mutation (SNP) | VAF 549/1015 reads (54%) | catalogued as rs756797592, COSV56630812; called by muse, mutect2, varscan2
- TYRO3 | c.1376G>C p.R459P | Missense Mutation (SNP) | VAF 132/370 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV104377948; called by muse, mutect2, varscan2
- USP27X | c.665C>T p.T222M | Missense Mutation (SNP) | VAF 34/408 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1557162632; called by muse, mutect2
- VN1R4 | c.487G>T p.D163Y | Missense Mutation (SNP) | VAF 40/371 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.317); catalogued as COSV100237584, COSV60805600; called by muse, mutect2, varscan2
- ZIC4 | c.887C>A p.S296Y | Missense Mutation (SNP) | VAF 206/708 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.3); catalogued as COSV101267986; called by mutect2, varscan2
- ZNF430 | c.1088A>G p.H363R | Missense Mutation (SNP) | VAF 47/295 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as rs757280080; called by muse, mutect2, varscan2
- ZNF496 | c.128G>T p.R43L | Missense Mutation (SNP) | VAF 282/830 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV54174957, COSV54180417; called by muse, mutect2, varscan2
- ZNF676 | c.1056del p.W352Cfs*178 (on ENST00000650058; = p.W320Cfs*178 on NM_001001411.3) | Frame Shift Del (DEL) | VAF 220/598 reads (37%) | catalogued as COSV101236216, COSV101236247; called by pindel, varscan2
- ZNF691 | c.403C>T p.R135W (on ENST00000372502; = p.R104W on NM_015911.3) | Missense Mutation (SNP) | VAF 104/433 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs368885981, COSV65289284; called by muse, mutect2, varscan2
- ZNF804A | c.367C>A p.L123I | Missense Mutation (SNP) | VAF 81/204 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV56469794; called by muse, mutect2, varscan2
- ZNF804A | c.3452T>C p.V1151A | Missense Mutation (SNP) | VAF 140/371 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.243); catalogued as rs1402671634; called by muse, mutect2, varscan2
- ZUP1 | c.1225G>T p.G409W | Missense Mutation (SNP) | VAF 219/246 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754412333; called by muse, mutect2, varscan2
- ACOT2 | c.866G>T p.G289V | Missense Mutation (SNP) | VAF 260/290 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACSF3 | c.602A>G p.Y201C | Missense Mutation (SNP) | VAF 98/328 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACTN2 | c.1767C>A p.Y589* | Nonsense Mutation (SNP) | VAF 186/400 reads (47%) | called by muse, mutect2, varscan2
- ADAD2 | c.1708G>T p.G570W (on ENST00000315906 / NM_001145400.2; = p.G652W on NM_139174.4) | Missense Mutation (SNP) | VAF 122/374 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS16 | c.205G>T p.D69Y | Missense Mutation (SNP) | VAF 183/498 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ADCY8 | c.2345A>G p.Y782C | Missense Mutation (SNP) | VAF 420/850 reads (49%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- ADD1 | c.970G>C p.A324P | Missense Mutation (SNP) | VAF 125/277 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADGRG7 | c.1049G>A p.S350N | Missense Mutation (SNP) | VAF 93/404 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- AGBL1 | c.3156G>C p.Q1052H | Missense Mutation (SNP) | VAF 273/355 reads (77%) | SIFT tolerated (0.13); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- AHNAK | c.7635G>T p.K2545N | Missense Mutation (SNP) | VAF 415/522 reads (80%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- AHNAK2 | c.11530G>T p.G3844W | Missense Mutation (SNP) | VAF 242/534 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- ALPL | c.433A>T p.N145Y | Missense Mutation (SNP) | VAF 58/412 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- AMY2B | c.742G>T p.E248* | Nonsense Mutation (SNP) | VAF 58/298 reads (19%) | called by muse, mutect2
- ANK3 | c.8792G>T p.R2931M | Missense Mutation (SNP) | VAF 70/241 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.533); called by mutect2, varscan2
- ANKRD17 | c.2860C>T p.Q954* | Nonsense Mutation (SNP) | VAF 73/434 reads (17%) | called by muse, mutect2, varscan2
- ANO4 | c.281G>T p.C94F | Missense Mutation (SNP) | VAF 326/326 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- APC2 | c.3671C>A p.P1224H | Missense Mutation (SNP) | VAF 447/448 reads (100%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- AR | c.517G>T p.G173C | Missense Mutation (SNP) | VAF 396/396 reads (100%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- ARAP2 | c.302A>G p.N101S | Missense Mutation (SNP) | VAF 31/572 reads (5%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); called by muse, mutect2
- ARRDC4 | c.578del p.G193Vfs*5 | Frame Shift Del (DEL) | VAF 272/465 reads (58%) | called by mutect2, pindel, varscan2
- ASPM | c.4172A>T p.K1391I | Missense Mutation (SNP) | VAF 60/487 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- ATP13A1 | c.448A>G p.N150D | Missense Mutation (SNP) | VAF 243/447 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- ATP9A | c.2619A>C p.Q873H | Missense Mutation (SNP) | VAF 78/525 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- AWAT1 | c.259C>A p.L87M | Missense Mutation (SNP) | VAF 332/333 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- B3GAT2 | c.437G>C p.R146P | Missense Mutation (SNP) | VAF 430/462 reads (93%) | SIFT tolerated (0.31); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- BLK | c.799G>C p.A267P | Missense Mutation (SNP) | VAF 121/229 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BMI1 | c.471G>T p.E157D | Missense Mutation (SNP) | VAF 18/370 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, mutect2
- BMP8B | c.898G>T p.V300F | Missense Mutation (SNP) | VAF 186/666 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- BRINP2 | c.157C>T p.H53Y | Missense Mutation (SNP) | VAF 114/576 reads (20%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- BTNL8 | c.542C>A p.T181K | Missense Mutation (SNP) | VAF 85/297 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- C8B | c.1308del p.T437Pfs*12 | Frame Shift Del (DEL) | VAF 72/446 reads (16%) | called by mutect2, pindel, varscan2
- CACNA1C | c.4871T>A p.I1624N | Missense Mutation (SNP) | VAF 137/193 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- CACNA1E | c.2861C>A p.T954N | Missense Mutation (SNP) | VAF 70/422 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CACNA1S | c.5540G>T p.G1847V | Missense Mutation (SNP) | VAF 398/832 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CADM2 | c.380C>A p.P127H (on ENST00000407528 / NM_001167674.2; = p.P129H on NM_153184.4) | Missense Mutation (SNP) | VAF 69/260 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAGE1 | c.489A>T p.E163D (on ENST00000512086; = p.E27D on NM_205864.3) | Missense Mutation (SNP) | VAF 91/448 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- CALHM4 | c.376G>T p.G126C | Missense Mutation (SNP) | VAF 391/413 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAPN13 | c.1561C>A p.L521I | Missense Mutation (SNP) | VAF 234/399 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CAPN15 | c.1757G>T p.R586L | Missense Mutation (SNP) | VAF 123/373 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CARS1 | c.1613G>A p.R538K | Missense Mutation (SNP) | VAF 261/586 reads (45%) | SIFT tolerated (0.92); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CASQ2 | c.406G>C p.E136Q | Missense Mutation (SNP) | VAF 162/357 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- CCDC168 | c.15510A>T p.L5170F | Missense Mutation (SNP) | VAF 181/401 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- CCDC80 | c.1746G>C p.K582N | Missense Mutation (SNP) | VAF 294/590 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.261); called by mutect2, varscan2
- CCNI | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 92/202 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- CD1D | c.881A>T p.Y294F | Missense Mutation (SNP) | VAF 62/332 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.44); called by muse, mutect2, varscan2
- CD247 | c.57A>T p.T19= | Splice Region (SNP) | VAF 82/424 reads (19%) | called by muse, mutect2, varscan2
- CD5L | c.691G>T p.D231Y | Missense Mutation (SNP) | VAF 89/270 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CD70 | c.479C>A p.P160H | Missense Mutation (SNP) | VAF 112/359 reads (31%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- CDC42EP4 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 36/292 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, varscan2
- CEP162 | c.3216G>T p.Q1072H | Missense Mutation (SNP) | VAF 278/301 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CEP290 | c.3586G>T p.E1196* | Nonsense Mutation (SNP) | VAF 349/350 reads (100%) | called by muse, mutect2, varscan2
- CFAP46 | c.4594G>C p.E1532Q | Missense Mutation (SNP) | VAF 98/332 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by muse, mutect2
- CFTR | c.139G>T p.D47Y | Missense Mutation (SNP) | VAF 113/314 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHAD | c.416C>A p.P139H | Missense Mutation (SNP) | VAF 118/419 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- CLDN15 | c.147G>C p.W49C | Missense Mutation (SNP) | VAF 81/487 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLRN1 | c.347C>A p.T116K (on ENST00000327047 / NM_174878.3; = p.T40K on NM_052995.2) | Missense Mutation (SNP) | VAF 252/574 reads (44%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- CNGA2 | c.399G>T p.L133F | Missense Mutation (SNP) | VAF 18/297 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.098); called by muse, mutect2
- CNGB3 | c.1505T>A p.L502Q | Missense Mutation (SNP) | VAF 151/638 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by mutect2, varscan2
- COL16A1 | c.3194C>T p.P1065L | Missense Mutation (SNP) | VAF 84/432 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL23A1 | c.1037C>G p.A346G | Missense Mutation (SNP) | VAF 12/264 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); called by muse, mutect2
- COL4A5 | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 282/282 reads (100%) | SIFT tolerated (0.24); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- COL5A2 | c.712C>A p.P238T | Missense Mutation (SNP) | VAF 182/349 reads (52%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL9A3 | c.477T>A p.P159= | Splice Region (SNP) | VAF 140/467 reads (30%) | called by muse, mutect2, varscan2
- CPVL | c.823A>G p.I275V | Missense Mutation (SNP) | VAF 47/384 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CRACD | c.2978C>A p.A993E | Missense Mutation (SNP) | VAF 212/429 reads (49%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- CRELD1 | c.544G>T p.D182Y | Missense Mutation (SNP) | VAF 240/591 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- CSMD1 | c.5250C>A p.Y1750* (on ENST00000520002; = p.Y1749* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 136/263 reads (52%) | called by muse, mutect2, varscan2
- CSMD3 | c.4345C>A p.P1449T (on ENST00000297405 / NM_001363185.1; = p.P1345T on NM_052900.3) | Missense Mutation (SNP) | VAF 61/262 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- CTAGE6 | c.904del p.E302Kfs*6 | Frame Shift Del (DEL) | VAF 32/130 reads (25%) | called by mutect2, varscan2
- CTNNA2 | c.663C>A p.Y221* | Nonsense Mutation (SNP) | VAF 93/719 reads (13%) | called by muse, mutect2, varscan2
- CUX2 | c.2912C>A p.P971H | Missense Mutation (SNP) | VAF 186/312 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- DCC | c.2006G>C p.G669A | Missense Mutation (SNP) | VAF 59/286 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- DGKQ | c.595G>C p.V199L | Missense Mutation (SNP) | VAF 209/680 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DHX40 | c.2132C>G p.A711G | Missense Mutation (SNP) | VAF 65/276 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- DLC1 | c.433G>A p.G145S | Missense Mutation (SNP) | VAF 352/352 reads (100%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- DLST | c.1273C>T p.R425W | Missense Mutation (SNP) | VAF 87/282 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH14 | c.6104A>G p.Y2035C (on ENST00000445597; = p.Y2688C on NM_001367479.1) | Missense Mutation (SNP) | VAF 207/615 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- DNAH5 | c.8233G>A p.G2745R | Missense Mutation (SNP) | VAF 107/311 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- DNAH9 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 204/205 reads (100%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- DNAH9 | c.6445G>T p.V2149L | Missense Mutation (SNP) | VAF 88/141 reads (62%) | SIFT tolerated (0.09); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- DOK2 | c.884A>T p.Q295L | Missense Mutation (SNP) | VAF 288/530 reads (54%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- DOT1L | c.499G>T p.G167C | Missense Mutation (SNP) | VAF 228/228 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DPH6 | c.414A>T p.L138F | Missense Mutation (SNP) | VAF 104/159 reads (65%) | SIFT deleterious (0.03); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- DRD2 | c.254C>A p.T85K | Missense Mutation (SNP) | VAF 91/341 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- DSCAM | c.4036A>T p.I1346F | Missense Mutation (SNP) | VAF 23/607 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- DYNC1LI2 | c.555G>T p.M185I | Missense Mutation (SNP) | VAF 42/194 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0); called by mutect2, varscan2
- DYNC2H1 | c.4681C>A p.H1561N | Missense Mutation (SNP) | VAF 141/271 reads (52%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DYRK1A | c.1434C>G p.F478L | Missense Mutation (SNP) | VAF 92/328 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by mutect2, varscan2
- DYSF | c.1641G>T p.G547= | Splice Region (SNP) | VAF 266/359 reads (74%) | called by muse, mutect2, varscan2
- EFHB | c.766del p.D256Ifs*23 | Frame Shift Del (DEL) | VAF 52/360 reads (14%) | called by mutect2, pindel, varscan2
- EHD3 | c.1474A>G p.K492E | Missense Mutation (SNP) | VAF 428/518 reads (83%) | SIFT tolerated (0.13); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- ELAVL1 | c.305T>C p.V102A | Missense Mutation (SNP) | VAF 14/280 reads (5%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2
- ERC2 | c.2629G>A p.A877T | Missense Mutation (SNP) | VAF 78/386 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- ERP44 | c.383C>T p.S128L | Missense Mutation (SNP) | VAF 212/362 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.337); called by muse, mutect2, varscan2
- EXOC3L1 | c.1930G>T p.A644S | Missense Mutation (SNP) | VAF 55/269 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- F5 | c.6491G>T p.W2164L | Missense Mutation (SNP) | VAF 114/337 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM135B | c.1950G>T p.E650D | Missense Mutation (SNP) | VAF 90/700 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM71E2 | c.778C>A p.P260T | Missense Mutation (SNP) | VAF 83/407 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- FAM83C | c.903C>A p.Y301* | Nonsense Mutation (SNP) | VAF 116/730 reads (16%) | called by muse, mutect2, varscan2
- FAM83H | c.3200A>G p.N1067S | Missense Mutation (SNP) | VAF 353/1222 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAT3 | c.3338C>T p.S1113L | Missense Mutation (SNP) | VAF 83/360 reads (23%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- FCRL1 | c.725T>G p.F242C | Missense Mutation (SNP) | VAF 13/438 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- FER1L6 | c.5182T>A p.C1728S | Missense Mutation (SNP) | VAF 172/945 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FHAD1 | c.4079T>C p.L1360P | Missense Mutation (SNP) | VAF 149/393 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FLNC | c.6688C>A p.R2230S | Missense Mutation (SNP) | VAF 200/568 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FOXD4L4 | c.664C>A p.P222T | Missense Mutation (SNP) | VAF 70/460 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.052); called by mutect2, varscan2
- FUBP1 | c.1220G>T p.G407V | Missense Mutation (SNP) | VAF 136/373 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FZD10 | c.110T>C p.I37T | Missense Mutation (SNP) | VAF 312/512 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- G2E3 | c.41G>T p.C14F | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GALNT15 | c.1849C>A p.L617M | Missense Mutation (SNP) | VAF 68/319 reads (21%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- GASK1B | c.780T>A p.C260* | Nonsense Mutation (SNP) | VAF 408/538 reads (76%) | called by muse, mutect2, varscan2
- GDI2 | c.354G>T p.K118N | Missense Mutation (SNP) | VAF 89/214 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- GMNC | c.584T>A p.L195* | Nonsense Mutation (SNP) | VAF 70/420 reads (17%) | called by muse, mutect2, varscan2
- GNPAT | c.1262G>C p.G421A | Missense Mutation (SNP) | VAF 172/372 reads (46%) | SIFT tolerated (0.95); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- GOLGA6L7 | c.653C>A p.P218Q | Missense Mutation (SNP) | VAF 169/317 reads (53%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- GPR27 | c.1038G>T p.R346S | Missense Mutation (SNP) | VAF 350/464 reads (75%) | SIFT deleterious (0); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- GSKIP | c.88A>T p.M30L | Missense Mutation (SNP) | VAF 238/495 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- H6PD | c.1187G>T p.R396L | Missense Mutation (SNP) | VAF 128/508 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- HAS1 | c.760C>A p.L254M | Missense Mutation (SNP) | VAF 98/489 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- HAS1 | c.445C>A p.R149S | Missense Mutation (SNP) | VAF 267/688 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- HNRNPA1L2 | c.40A>T p.R14W | Missense Mutation (SNP) | VAF 153/366 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- HOOK3 | c.1520A>C p.E507A | Missense Mutation (SNP) | VAF 37/282 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.15); called by mutect2, varscan2
- HOXA11 | c.262C>A p.L88I | Missense Mutation (SNP) | VAF 682/960 reads (71%) | SIFT tolerated (0.51); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HRNR | c.1789T>A p.Y597N | Missense Mutation (SNP) | VAF 264/658 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- HSD3B2 | c.847T>A p.W283R | Missense Mutation (SNP) | VAF 209/514 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HYDIN | c.13605del p.F4536Lfs*16 | Frame Shift Del (DEL) | VAF 160/322 reads (50%) | called by mutect2, pindel, varscan2
- IARS2 | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 114/349 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGF2BP3 | c.1130C>A p.P377Q | Missense Mutation (SNP) | VAF 136/459 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- IGKV2D-24 | c.56G>A p.S19N | Missense Mutation (SNP) | VAF 132/173 reads (76%) | SIFT tolerated (0.15); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- IGKV2D-30 | c.153C>A p.Y51* | Nonsense Mutation (SNP) | VAF 58/310 reads (19%) | called by muse, mutect2, varscan2
- IGKV3-15 | c.256G>T p.G86W | Missense Mutation (SNP) | VAF 110/997 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IRS1 | c.289G>T p.A97S | Missense Mutation (SNP) | VAF 183/512 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IRS2 | c.3178T>A p.S1060T | Missense Mutation (SNP) | VAF 367/646 reads (57%) | SIFT tolerated (0.25); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- IST1 | c.313C>G p.L105V (on ENST00000535424 / NM_001270976.1; = p.L92V on NM_014761.4) | Missense Mutation (SNP) | VAF 126/128 reads (98%) | SIFT deleterious (0.05); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- ITGA8 | c.679C>G p.Q227E | Missense Mutation (SNP) | VAF 67/174 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- KCNG1 | c.205G>T p.V69L | Missense Mutation (SNP) | VAF 97/590 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KCNH8 | c.373C>A p.L125I | Missense Mutation (SNP) | VAF 118/181 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KCNJ6 | c.1013C>A p.P338H | Missense Mutation (SNP) | VAF 250/319 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- KIAA2012 | c.2765del p.G922Afs*39 | Frame Shift Del (DEL) | VAF 157/643 reads (24%) | called by mutect2, pindel, varscan2
- KIF4A | c.433A>C p.N145H | Missense Mutation (SNP) | VAF 85/176 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- KIR3DL1 | c.76C>G p.Q26E | Missense Mutation (SNP) | VAF 89/300 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- KIRREL1 | c.1636G>T p.E546* | Nonsense Mutation (SNP) | VAF 150/369 reads (41%) | called by muse, mutect2, varscan2
- KLHL1 | c.1546G>T p.G516C | Missense Mutation (SNP) | VAF 316/316 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KMO | c.1103G>T p.R368L | Missense Mutation (SNP) | VAF 144/354 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KPRP | c.1388G>T p.C463F | Missense Mutation (SNP) | VAF 19/577 reads (3%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2
- KRTAP12-2 | c.61C>A p.Q21K | Missense Mutation (SNP) | VAF 179/493 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- KRTAP6-2 | c.164G>T p.G55V | Missense Mutation (SNP) | VAF 126/267 reads (47%) | PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- KRTAP9-6 | c.183C>A p.C61* | Nonsense Mutation (SNP) | VAF 55/157 reads (35%) | called by muse, mutect2, varscan2
- KRTAP9-7 | c.168C>A p.C56* | Nonsense Mutation (SNP) | VAF 112/356 reads (31%) | called by muse, mutect2, varscan2
- LAMA5 | c.8809G>T p.D2937Y | Missense Mutation (SNP) | VAF 114/366 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- LAMB2 | c.2052G>T p.E684D | Missense Mutation (SNP) | VAF 225/329 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- LAMP3 | c.238A>C p.T80P | Missense Mutation (SNP) | VAF 159/539 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LEMD1 | c.165del p.R56Efs*47 (on ENST00000367151; = p.R56Efs*74 on NM_001001552.5) | Frame Shift Del (DEL) | VAF 279/686 reads (41%) | called by mutect2, pindel, varscan2
- LGI4 | c.628+8G>A | Splice Region (SNP) | VAF 302/556 reads (54%) | called by muse, varscan2
- LILRA2 | c.94T>C p.W32R | Missense Mutation (SNP) | VAF 230/468 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.258); called by muse, varscan2
- LILRB1 | c.500C>A p.P167H (on ENST00000427581; = p.P131H on NM_006669.6) | Missense Mutation (SNP) | VAF 124/360 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LILRB5 | c.994C>T p.P332S | Missense Mutation (SNP) | VAF 282/631 reads (45%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- LIPI | c.94G>A p.V32M | Missense Mutation (SNP) | VAF 167/228 reads (73%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LMX1A | c.457G>T p.E153* | Nonsense Mutation (SNP) | VAF 65/369 reads (18%) | called by muse, mutect2, varscan2
- LOXL1 | c.176C>T p.S59L | Missense Mutation (SNP) | VAF 597/936 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LOXL1 | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 776/1184 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- LPA | c.2908C>A p.H970N | Missense Mutation (SNP) | VAF 184/217 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, varscan2
- LRGUK | c.2240G>T p.R747L | Missense Mutation (SNP) | VAF 89/458 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- LRP1B | c.10057C>A p.P3353T | Missense Mutation (SNP) | VAF 107/186 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRC66 | c.2064G>T p.Q688H | Missense Mutation (SNP) | VAF 189/386 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- LRRC66 | c.627A>T p.K209N | Missense Mutation (SNP) | VAF 81/281 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- LRRCC1 | c.2140G>T p.A714S | Missense Mutation (SNP) | VAF 93/376 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- LRRTM1 | c.1255G>T p.A419S | Missense Mutation (SNP) | VAF 102/584 reads (17%) | SIFT tolerated (0.68); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MACF1 | c.824-1G>T p.X275_splice | Splice Site (SNP) | VAF 61/190 reads (32%) | called by muse, mutect2, varscan2
- MAGEB6 | c.285C>A p.S95R | Missense Mutation (SNP) | VAF 122/122 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- MAP4K1 | c.1352C>A p.T451N | Missense Mutation (SNP) | VAF 117/273 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- MEI4 | c.907G>A p.A303T | Missense Mutation (SNP) | VAF 23/328 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.113); called by muse, mutect2
- MKLN1 | c.28G>T p.A10S | Missense Mutation (SNP) | VAF 168/429 reads (39%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MMP16 | c.1412C>A p.P471H | Missense Mutation (SNP) | VAF 215/446 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- MRC1 | c.227G>C p.G76A | Missense Mutation (SNP) | VAF 275/370 reads (74%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MRPL39 | c.556G>C p.D186H | Missense Mutation (SNP) | VAF 197/302 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- MS4A14 | c.406G>T p.D136Y | Missense Mutation (SNP) | VAF 83/438 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MSH4 | c.768G>T p.Q256H | Missense Mutation (SNP) | VAF 69/338 reads (20%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- MSL3 | c.895A>G p.T299A (on ENST00000312196 / NM_078629.4; = p.T133A on NM_006800.4) | Missense Mutation (SNP) | VAF 58/58 reads (100%) | SIFT tolerated (0.44); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MST1 | c.1942A>T p.I648F | Missense Mutation (SNP) | VAF 302/399 reads (76%) | SIFT deleterious (0.05); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- MTOR | c.5461A>T p.S1821C | Missense Mutation (SNP) | VAF 116/470 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- MUC3A | c.9051A>G p.L3017= | Splice Region (SNP) | VAF 56/521 reads (11%) | called by muse, mutect2, varscan2
- MVP | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 39/130 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- MYH2 | c.5809G>T p.V1937F | Missense Mutation (SNP) | VAF 56/175 reads (32%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- MYOM3 | c.1432+1G>T p.X478_splice | Splice Site (SNP) | VAF 96/241 reads (40%) | called by muse, mutect2, varscan2
- NBPF11 | c.1239G>T p.Q413H | Missense Mutation (SNP) | VAF 55/510 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- NELL1 | c.1586G>A p.C529Y | Missense Mutation (SNP) | VAF 136/326 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- NES | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 116/624 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- NIN | c.2014C>T p.L672F | Missense Mutation (SNP) | VAF 150/360 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NKAIN2 | c.323G>T p.W108L | Missense Mutation (SNP) | VAF 342/368 reads (93%) | SIFT deleterious (0); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- NKAPL | c.821C>G p.T274S | Missense Mutation (SNP) | VAF 172/487 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- NKX3-2 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 111/615 reads (18%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOBOX | c.184C>A p.L62I | Missense Mutation (SNP) | VAF 135/374 reads (36%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOLC1 | c.1225C>T p.P409S | Missense Mutation (SNP) | VAF 111/345 reads (32%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOSTRIN | c.1357C>A p.Q453K (on ENST00000317647 / NM_001039724.4; = p.Q375K on NM_052946.3) | Missense Mutation (SNP) | VAF 218/405 reads (54%) | SIFT tolerated (0.41); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- NPR3 | c.1182C>A p.N394K | Missense Mutation (SNP) | VAF 109/299 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NRAP | c.5176_*7delinsGCCCTGCTGTTGTGAGCCATG | Nonstop Mutation (DEL) | VAF 59/261 reads (23%) | called by pindel, varscan2*
- NSUN7 | c.929T>A p.M310K | Missense Mutation (SNP) | VAF 189/389 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- OCA2 | c.611G>T p.W204L | Missense Mutation (SNP) | VAF 439/554 reads (79%) | SIFT deleterious (0.01); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- OGFR | c.644G>T p.R215L | Missense Mutation (SNP) | VAF 87/596 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- OR10K2 | c.219C>A p.Y73* | Nonsense Mutation (SNP) | VAF 66/375 reads (18%) | called by muse, mutect2, varscan2
- OR14C36 | c.253C>A p.L85M | Missense Mutation (SNP) | VAF 230/495 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- OR14K1 | c.254C>A p.A85D | Missense Mutation (SNP) | VAF 214/427 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- OR1C1 | c.941A>T p.Q314L | Missense Mutation (SNP) | VAF 124/269 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR2H1 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 199/1274 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- OR52E5 | c.15C>A p.N5K | Missense Mutation (SNP) | VAF 68/336 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR5H15 | c.354G>T p.M118I | Missense Mutation (SNP) | VAF 275/588 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- OR5I1 | c.522T>A p.N174K | Missense Mutation (SNP) | VAF 59/341 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- OR8G5 | c.915del p.R308Efs*66 (on ENST00000641992; = p.R308Efs*? on NM_001005198.1) | Frame Shift Del (DEL) | VAF 159/219 reads (73%) | called by mutect2, pindel, varscan2
- OSBPL3 | c.1020_1027+2delinsTC p.X340_splice | Splice Site (DEL) | VAF 95/351 reads (27%) | called by pindel, varscan2*
- OTOP1 | c.23C>A p.P8H | Missense Mutation (SNP) | VAF 173/561 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- P3H1 | c.2055+3G>A | Splice Region (SNP) | VAF 112/607 reads (18%) | called by muse, mutect2, varscan2
- PAK6 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 221/310 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- PAPPA2 | c.313A>T p.S105C | Missense Mutation (SNP) | VAF 207/514 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- PCARE | c.2276T>A p.L759H | Missense Mutation (SNP) | VAF 358/468 reads (76%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- PCDHA1 | c.1258G>T p.V420F | Missense Mutation (SNP) | VAF 333/333 reads (100%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- PCDHB2 | c.1687G>T p.V563L | Missense Mutation (SNP) | VAF 135/490 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- PCDHB8 | c.286C>G p.L96V | Missense Mutation (SNP) | VAF 54/292 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- PCNX4 | c.98G>T p.G33V | Missense Mutation (SNP) | VAF 180/379 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCSK5 | c.3956T>A p.V1319E | Missense Mutation (SNP) | VAF 82/254 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2
- PCYT1B | c.889G>A p.G297R | Missense Mutation (SNP) | VAF 64/64 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.15); called by muse, varscan2
- PGD | c.201G>T p.K67N | Missense Mutation (SNP) | VAF 87/417 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- PIEZO2 | c.3706G>A p.A1236T | Missense Mutation (SNP) | VAF 124/368 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PIK3CD | c.1723_1740del p.P575_L580del | In Frame Del (DEL) | VAF 76/265 reads (29%) | called by mutect2, pindel, varscan2
- PITPNM3 | c.1876C>T p.Q626* | Nonsense Mutation (SNP) | VAF 74/258 reads (29%) | called by muse, mutect2, varscan2
- PKHD1 | c.5332G>T p.A1778S | Missense Mutation (SNP) | VAF 491/695 reads (71%) | SIFT tolerated (0.32); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- PKP1 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 175/386 reads (45%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- PLEC | c.11705_11710del p.E3902_R3903del (on ENST00000322810 / NM_201380.4; = p.E3792_R3793del on NM_000445.5) | In Frame Del (DEL) | VAF 225/924 reads (24%) | called by mutect2, pindel, varscan2
- PLEKHA7 | c.2635G>T p.V879F | Missense Mutation (SNP) | VAF 287/549 reads (52%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- PLEKHA7 | c.1563G>T p.W521C | Missense Mutation (SNP) | VAF 246/499 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- PLEKHB2 | c.556G>T p.A186S | Missense Mutation (SNP) | VAF 75/156 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- PLEKHM1 | c.1857_1858insT p.V620Cfs*15 | Frame Shift Ins (INS) | VAF 160/584 reads (27%) | called by mutect2, pindel, varscan2
- PLXDC1 | c.577_579del p.V193del | In Frame Del (DEL) | VAF 42/248 reads (17%) | called by pindel, varscan2
- PLXNA4 | c.3346G>T p.E1116* | Nonsense Mutation (SNP) | VAF 93/463 reads (20%) | called by muse, mutect2, varscan2
- PNMA8B | c.992_1021del p.E331_P341delinsA | In Frame Del (DEL) | VAF 65/478 reads (14%) | called by mutect2, pindel, varscan2
- POLRMT | c.2360A>T p.Q787L | Missense Mutation (SNP) | VAF 465/465 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- POTEF | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); called by mutect2, varscan2
- POU3F2 | c.163C>A p.L55I | Missense Mutation (SNP) | VAF 26/512 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); called by muse, mutect2
- POU5F1B | c.940G>T p.A314S | Missense Mutation (SNP) | VAF 296/1683 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- PPDPFL | c.213A>G p.I71M | Missense Mutation (SNP) | VAF 60/391 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRPF8 | c.5794G>T p.A1932S | Missense Mutation (SNP) | VAF 169/275 reads (61%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRRT4 | c.1625C>A p.P542Q | Missense Mutation (SNP) | VAF 256/647 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- PRSS38 | c.731A>T p.D244V | Missense Mutation (SNP) | VAF 128/438 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- PSMA2 | c.588G>T p.K196N | Missense Mutation (SNP) | VAF 32/452 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); called by muse, mutect2
- PTGS2 | c.412C>A p.L138I | Missense Mutation (SNP) | VAF 170/442 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- PTPRN2 | c.2077G>T p.V693F | Missense Mutation (SNP) | VAF 198/605 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- PVR | c.797G>T p.C266F | Missense Mutation (SNP) | VAF 165/397 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- PZP | c.1873A>G p.N625D | Missense Mutation (SNP) | VAF 130/318 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- RABL6 | c.1145A>T p.E382V | Missense Mutation (SNP) | VAF 136/213 reads (64%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- RAG2 | c.733C>A p.P245T | Missense Mutation (SNP) | VAF 196/381 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RASSF10 | c.1433G>C p.G478A | Missense Mutation (SNP) | VAF 62/295 reads (21%) | SIFT tolerated (0.92); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RBM22 | c.1182G>T p.M394I | Missense Mutation (SNP) | VAF 232/232 reads (100%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RBM46 | c.328A>T p.T110S | Missense Mutation (SNP) | VAF 250/335 reads (75%) | SIFT tolerated (0.31); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RFTN2 | c.211C>T p.L71F | Missense Mutation (SNP) | VAF 199/349 reads (57%) | SIFT tolerated (0.53); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- RFX6 | c.364C>T p.Q122* | Nonsense Mutation (SNP) | VAF 211/229 reads (92%) | called by muse, mutect2, varscan2
- RGS22 | c.3026A>G p.E1009G | Missense Mutation (SNP) | VAF 166/346 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- RP1 | c.5947A>G p.N1983D | Missense Mutation (SNP) | VAF 14/433 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2
- RPTN | c.1903G>T p.G635* | Nonsense Mutation (SNP) | VAF 125/598 reads (21%) | called by muse, mutect2, varscan2
- RSPO1 | c.440A>T p.Q147L | Missense Mutation (SNP) | VAF 122/305 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- RXFP1 | c.609G>T p.L203= | Splice Region (SNP) | VAF 57/266 reads (21%) | called by muse, mutect2, varscan2
- SALL4 | c.2978G>A p.G993E | Missense Mutation (SNP) | VAF 216/654 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- SCAF1 | c.709G>T p.A237S | Missense Mutation (SNP) | VAF 97/233 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SCN10A | c.4389C>A p.N1463K | Missense Mutation (SNP) | VAF 44/201 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SEMA6D | c.255G>T p.M85I | Missense Mutation (SNP) | VAF 63/225 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEMA6D | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 63/111 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SENP5 | c.1177G>C p.E393Q | Missense Mutation (SNP) | VAF 112/379 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- SERF2 | c.165G>C p.K55N | Missense Mutation (SNP) | VAF 225/329 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SERPINA11 | c.1210G>C p.E404Q | Missense Mutation (SNP) | VAF 238/502 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- SESN2 | c.689C>A p.A230E | Missense Mutation (SNP) | VAF 29/663 reads (4%) | SIFT tolerated (0.65); PolyPhen benign (0.098); called by muse, mutect2
- SETBP1 | c.1504A>T p.M502L | Missense Mutation (SNP) | VAF 97/402 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- SH3GLB1 | c.700C>T p.Q234* | Nonsense Mutation (SNP) | VAF 121/235 reads (51%) | called by muse, mutect2, varscan2
- SLC12A7 | c.2566G>T p.G856C | Missense Mutation (SNP) | VAF 539/1193 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC17A6 | c.836G>T p.R279L | Missense Mutation (SNP) | VAF 128/269 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- SLC18A1 | c.1146+1G>C p.X382_splice | Splice Site (SNP) | VAF 74/343 reads (22%) | called by muse, mutect2, varscan2
- SLC28A3 | c.1535G>A p.G512D | Missense Mutation (SNP) | VAF 98/296 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC34A2 | c.1041_1042insA p.A348Sfs*59 | Frame Shift Ins (INS) | VAF 141/457 reads (31%) | called by mutect2, pindel, varscan2
- SLC38A2 | c.62G>C p.S21T | Missense Mutation (SNP) | VAF 70/411 reads (17%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- SNRNP200 | c.3915G>T p.Q1305H | Missense Mutation (SNP) | VAF 71/265 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- SNX25 | c.270G>T p.L90F | Missense Mutation (SNP) | VAF 71/281 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SORCS3 | c.1981G>T p.E661* | Nonsense Mutation (SNP) | VAF 45/219 reads (21%) | called by muse, mutect2, varscan2
- SPECC1 | c.2458G>T p.V820F | Missense Mutation (SNP) | VAF 152/431 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SPEM1 | c.434C>A p.S145Y | Missense Mutation (SNP) | VAF 313/314 reads (100%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- SPON1 | c.269T>A p.F90Y | Missense Mutation (SNP) | VAF 46/308 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- SUN1 | c.1453A>C p.K485Q (on ENST00000405266 / NM_001367651.1; = p.K365Q on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 262/391 reads (67%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- SV2C | c.847T>C p.C283R | Missense Mutation (SNP) | VAF 181/182 reads (99%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- SVEP1 | c.8966G>T p.C2989F | Missense Mutation (SNP) | VAF 100/291 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SYNE3 | c.1931G>T p.R644L | Missense Mutation (SNP) | VAF 149/435 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- TACC1 | c.175G>T p.G59C | Missense Mutation (SNP) | VAF 102/259 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TACR3 | c.958A>T p.I320F | Missense Mutation (SNP) | VAF 252/361 reads (70%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- TAF1L | c.391C>A p.Q131K | Missense Mutation (SNP) | VAF 293/596 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- TAL1 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 29/514 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2
- TBX22 | c.60C>A p.S20R | Missense Mutation (SNP) | VAF 396/396 reads (100%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TBX3 | c.1370C>A p.P457Q (on ENST00000257566 / NM_016569.4; = p.P437Q on NM_005996.4) | Missense Mutation (SNP) | VAF 474/792 reads (60%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TCERG1L | c.1239T>A p.D413E | Missense Mutation (SNP) | VAF 71/233 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TEC | c.858dup p.T287Yfs*12 | Frame Shift Ins (INS) | VAF 188/500 reads (38%) | called by mutect2, pindel, varscan2
- TENM2 | c.3104C>A p.P1035Q (on ENST00000518659 / NM_001122679.2; = p.P803Q on NM_001080428.3) | Missense Mutation (SNP) | VAF 96/314 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- TFAP2D | c.1034G>A p.C345Y | Missense Mutation (SNP) | VAF 63/232 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- TFIP11 | c.1433A>T p.H478L | Missense Mutation (SNP) | VAF 129/129 reads (100%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TGS1 | c.734A>G p.Y245C | Missense Mutation (SNP) | VAF 135/433 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TIMMDC1 | c.115C>T p.Q39* | Nonsense Mutation (SNP) | VAF 252/337 reads (75%) | called by muse, mutect2, varscan2
- TMC3 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 93/266 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TNR | c.989A>T p.E330V | Missense Mutation (SNP) | VAF 179/335 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- TNR | c.460C>A p.Q154K | Missense Mutation (SNP) | VAF 75/412 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- TP53RK | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 157/326 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- TPM1 | c.467A>G p.E156G | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- TRIM51 | c.886G>T p.A296S | Missense Mutation (SNP) | VAF 65/299 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TRPM7 | c.1895T>C p.M632T | Missense Mutation (SNP) | VAF 109/327 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRPM8 | c.173C>A p.T58N | Missense Mutation (SNP) | VAF 198/392 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- TTC22 | c.10del p.L4Wfs*8 | Frame Shift Del (DEL) | VAF 84/343 reads (24%) | called by mutect2, pindel, varscan2
- TTC39A | c.383A>G p.Y128C | Missense Mutation (SNP) | VAF 72/371 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTLL6 | c.565C>A p.P189T | Missense Mutation (SNP) | VAF 85/270 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTN | c.54800T>C p.V18267A (on ENST00000591111; = p.V10843A on NM_003319.4) | Missense Mutation (SNP) | VAF 40/561 reads (7%) | PolyPhen benign (0.109); called by muse, mutect2
- TULP4 | c.2014G>T p.V672L | Missense Mutation (SNP) | VAF 15/218 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2
- TUSC3 | c.50T>C p.L17P | Missense Mutation (SNP) | VAF 401/401 reads (100%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- TUT7 | c.3104A>T p.Q1035L | Missense Mutation (SNP) | VAF 141/231 reads (61%) | SIFT tolerated (0.1); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- TYW1B | c.1328C>A p.S443Y | Missense Mutation (SNP) | VAF 186/487 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- U2SURP | c.637C>T p.Q213* | Nonsense Mutation (SNP) | VAF 64/214 reads (30%) | called by muse, mutect2, varscan2
- UNC45B | c.1631T>A p.V544E | Missense Mutation (SNP) | VAF 117/436 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UNC5D | c.2332G>T p.V778L | Missense Mutation (SNP) | VAF 290/290 reads (100%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- UNC5D | c.2647A>C p.S883R | Missense Mutation (SNP) | VAF 250/250 reads (100%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- UNCX | c.1390G>T p.A464S | Missense Mutation (SNP) | VAF 81/276 reads (29%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- VPS13B | c.2139T>G p.H713Q | Missense Mutation (SNP) | VAF 102/790 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR59 | c.1573G>T p.A525S | Missense Mutation (SNP) | VAF 257/258 reads (100%) | SIFT tolerated (0.05); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- WDR87 | c.732A>T p.Q244H | Missense Mutation (SNP) | VAF 59/363 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WNT5B | c.424G>T p.G142C | Missense Mutation (SNP) | VAF 296/429 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- XIAP | c.1466C>G p.T489S | Missense Mutation (SNP) | VAF 259/260 reads (100%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- ZC4H2 | c.298G>T p.E100* | Nonsense Mutation (SNP) | VAF 180/447 reads (40%) | called by muse, mutect2, varscan2
- ZC4H2 | c.157G>C p.D53H | Missense Mutation (SNP) | VAF 416/418 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ZFHX4 | c.1299C>A p.S433R | Missense Mutation (SNP) | VAF 337/626 reads (54%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ZIC4 | c.689G>C p.G230A | Missense Mutation (SNP) | VAF 168/343 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- ZKSCAN8 | c.1022G>T p.W341L | Missense Mutation (SNP) | VAF 302/483 reads (63%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- ZNF143 | c.58G>T p.G20W | Missense Mutation (SNP) | VAF 176/333 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF208 | c.2975A>T p.K992M | Missense Mutation (SNP) | VAF 56/267 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ZNF431 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 47/217 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ZNF480 | c.1549G>T p.G517C | Missense Mutation (SNP) | VAF 63/395 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- ZNF530 | c.500C>A p.P167H | Missense Mutation (SNP) | VAF 65/558 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ZNF569 | c.1279A>T p.T427S | Missense Mutation (SNP) | VAF 185/370 reads (50%) | SIFT tolerated (0.7); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF721 | c.790C>A p.P264T (on ENST00000338977; = p.P276T on NM_133474.4) | Missense Mutation (SNP) | VAF 61/440 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ZNF799 | c.1736A>T p.E579V | Missense Mutation (SNP) | VAF 330/346 reads (95%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF800 | c.272A>G p.Y91C | Missense Mutation (SNP) | VAF 111/315 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF81 | c.1457A>T p.Q486L | Missense Mutation (SNP) | VAF 94/142 reads (66%) | SIFT tolerated (0.66); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- ZNF831 | c.2836C>G p.P946A | Missense Mutation (SNP) | VAF 448/685 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- ZNF84 | c.133G>T p.V45L | Missense Mutation (SNP) | VAF 182/182 reads (100%) | SIFT tolerated (0.36); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- ZNF99 | c.544T>C p.F182L | Missense Mutation (SNP) | VAF 44/169 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- ZPLD1 | c.353C>G p.A118G (on ENST00000466937 / NM_001329788.1; = p.A134G on NM_175056.2) | Missense Mutation (SNP) | VAF 50/436 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- ZYX | c.1300G>T p.E434* | Nonsense Mutation (SNP) | VAF 85/403 reads (21%) | called by muse, mutect2, varscan2
- ABHD13 | c.492A>T p.G164= | Silent (SNP) | VAF 282/282 reads (100%) | called by muse, mutect2, varscan2
- ACOT2 | c.867G>T p.G289= | Silent (SNP) | VAF 263/295 reads (89%) | called by muse, mutect2, varscan2
- ADAMTS1 | c.351A>G p.E117= | Silent (SNP) | VAF 268/374 reads (72%) | called by muse, mutect2, varscan2
- AMOTL1 | c.2499G>T p.L833= | Silent (SNP) | VAF 227/320 reads (71%) | called by muse, mutect2
- ANK2 | c.3459G>T p.V1153= | Silent (SNP) | VAF 104/404 reads (26%) | called by muse, mutect2, varscan2
- APOL5 | c.267C>A p.S89= | Silent (SNP) | VAF 360/360 reads (100%) | called by muse, mutect2, varscan2
- ARHGAP23 | c.1794G>T p.S598= | Silent (SNP) | VAF 245/545 reads (45%) | catalogued as rs778000637; called by muse, mutect2, varscan2
- ATP6V0C | c.336C>T p.I112= | Silent (SNP) | VAF 152/496 reads (31%) | catalogued as rs777875089; called by muse, mutect2, varscan2
- CACNA1E | c.5208G>T p.L1736= | Silent (SNP) | VAF 93/431 reads (22%) | catalogued as COSV62384641; called by muse, mutect2, varscan2
- CDH22 | c.684G>T p.T228= | Silent (SNP) | VAF 337/337 reads (100%) | catalogued as COSV64837665; called by muse, mutect2, varscan2
- CMA1 | c.66C>A p.I22= | Silent (SNP) | VAF 133/295 reads (45%) | catalogued as rs183530742; called by muse, mutect2, varscan2
- CNTNAP2 | c.1608G>T p.V536= | Silent (SNP) | VAF 173/301 reads (57%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.2763C>A p.S921= | Silent (SNP) | VAF 93/154 reads (60%) | called by muse, mutect2, varscan2
- COL15A1 | c.528C>A p.L176= | Silent (SNP) | VAF 181/293 reads (62%) | catalogued as COSV66647096; called by muse, mutect2, varscan2
- COQ10B | c.231A>G p.E77= | Silent (SNP) | VAF 10/276 reads (4%) | called by muse, mutect2
- COQ8B | c.180C>T p.R60= | Silent (SNP) | VAF 208/449 reads (46%) | called by muse, mutect2, varscan2
- CSMD3 | c.7584C>A p.L2528= (on ENST00000297405 / NM_001363185.1; = p.L2424= on NM_052900.3) | Silent (SNP) | VAF 103/456 reads (23%) | called by muse, mutect2, varscan2
- CSMD3 | c.4641G>T p.G1547= (on ENST00000297405 / NM_001363185.1; = p.G1443= on NM_052900.3) | Silent (SNP) | VAF 162/766 reads (21%) | catalogued as COSV52260985; called by muse, mutect2, varscan2
- DENND5B | c.834G>T p.L278= | Silent (SNP) | VAF 88/269 reads (33%) | called by muse, mutect2, varscan2
- DPP6 | c.2034G>T p.R678= (on ENST00000377770 / NM_001364500.2; = p.R616= on NM_001936.5) | Silent (SNP) | VAF 206/640 reads (32%) | called by muse, mutect2, varscan2
- DYM | c.297C>T p.F99= | Silent (SNP) | VAF 10/175 reads (6%) | catalogued as rs886053847; ClinVar: uncertain significance; called by muse, mutect2
- EME1 | c.138G>A p.V46= | Silent (SNP) | VAF 79/291 reads (27%) | catalogued as COSV99869184; called by muse, mutect2, varscan2
- EXD1 | c.498C>T p.C166= | Silent (SNP) | VAF 117/185 reads (63%) | catalogued as COSV100153545; called by muse, mutect2, varscan2
- EYA1 | c.1056A>T p.P352= | Silent (SNP) | VAF 143/332 reads (43%) | called by muse, mutect2, varscan2
- FAM47C | c.528G>C p.T176= | Silent (SNP) | VAF 130/130 reads (100%) | catalogued as COSV63727816; called by muse, mutect2, varscan2
- FBXO8 | c.24G>T p.V8= | Silent (SNP) | VAF 77/297 reads (26%) | called by muse, mutect2, varscan2
- FGGY | c.1395G>T p.V465= | Silent (SNP) | VAF 45/240 reads (19%) | called by muse, mutect2, varscan2
- FPGS | c.1050C>T p.H350= | Silent (SNP) | VAF 201/304 reads (66%) | called by muse, mutect2, varscan2
- FZD10 | c.252C>G p.R84= | Silent (SNP) | VAF 326/515 reads (63%) | called by muse, mutect2, varscan2
- GABRA6 | c.219G>A p.V73= | Silent (SNP) | VAF 61/195 reads (31%) | called by muse, mutect2, varscan2
- GIMAP7 | c.156G>T p.R52= | Silent (SNP) | VAF 172/564 reads (30%) | called by muse, mutect2, varscan2
- GLIS3 | c.1068C>T p.Y356= | Silent (SNP) | VAF 278/577 reads (48%) | catalogued as rs371355667; called by muse, mutect2, varscan2
- GLP2R | c.561C>A p.S187= | Silent (SNP) | VAF 73/223 reads (33%) | catalogued as COSV52322622, COSV52328662; called by muse, mutect2, varscan2
- GRID2IP | c.543G>T p.A181= | Silent (SNP) | VAF 116/799 reads (15%) | called by muse, mutect2, varscan2
- GRIN3B | c.1366C>T p.L456= | Silent (SNP) | VAF 99/366 reads (27%) | catalogued as rs371910067, COSV52263961; called by muse, mutect2, varscan2
- GRM6 | c.81G>A p.A27= | Silent (SNP) | VAF 54/145 reads (37%) | called by muse, mutect2, varscan2
- HEPH | c.42T>A p.V14= | Silent (SNP) | VAF 125/320 reads (39%) | called by muse, mutect2, varscan2
- HERC2 | c.11262G>A p.A3754= | Silent (SNP) | VAF 140/739 reads (19%) | catalogued as rs555809688; called by muse, mutect2, varscan2
- HIVEP1 | c.444C>T p.S148= | Silent (SNP) | VAF 345/697 reads (49%) | catalogued as rs763642376; called by muse, mutect2, varscan2
- HYDIN | c.3792C>A p.V1264= | Silent (SNP) | VAF 31/131 reads (24%) | catalogued as COSV66834334; called by muse, mutect2, varscan2
- KCNH4 | c.852C>G p.T284= | Silent (SNP) | VAF 88/257 reads (34%) | catalogued as COSV52916589; called by muse, mutect2, varscan2
- KCNK2 | c.588A>T p.L196= (on ENST00000444842 / NM_001017425.3; = p.L181= on NM_014217.4) | Silent (SNP) | VAF 64/546 reads (12%) | called by muse, mutect2, varscan2
- KCNN3 | c.807G>A p.K269= | Silent (SNP) | VAF 61/426 reads (14%) | called by muse, mutect2, varscan2
- KIF1A | c.558C>A p.V186= | Silent (SNP) | VAF 191/442 reads (43%) | called by muse, mutect2, varscan2
- KMT5C | c.177G>C p.R59= | Silent (SNP) | VAF 414/747 reads (55%) | catalogued as rs1348617615; called by muse, mutect2, varscan2
- KRTAP27-1 | c.141G>A p.L47= | Silent (SNP) | VAF 300/393 reads (76%) | catalogued as rs1292212429; called by muse, mutect2, varscan2
- LDLRAD2 | c.447C>A p.R149= | Silent (SNP) | VAF 108/582 reads (19%) | called by muse, mutect2, varscan2
- LMLN2 | c.156C>A p.T52= | Silent (SNP) | VAF 92/388 reads (24%) | catalogued as rs949378979; called by muse, mutect2, varscan2
- LOXL1 | c.504C>T p.R168= | Silent (SNP) | VAF 738/1121 reads (66%) | called by muse, varscan2
- LRRC7 | c.426A>G p.V142= (on ENST00000651989 / NM_001370785.2; = p.V109= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 19/194 reads (10%) | catalogued as COSV50436665; called by muse, mutect2, varscan2
- LRRN2 | c.390C>A p.T130= | Silent (SNP) | VAF 213/654 reads (33%) | called by muse, mutect2, varscan2
- LRTM2 | c.996C>A p.G332= | Silent (SNP) | VAF 205/310 reads (66%) | called by muse, mutect2, varscan2
- MED13L | c.6006A>G p.S2002= | Silent (SNP) | VAF 453/453 reads (100%) | called by muse, mutect2, varscan2
- MIB2 | c.2835T>A p.A945= | Silent (SNP) | VAF 111/592 reads (19%) | called by muse, mutect2, varscan2
- MKLN1 | c.27G>T p.A9= | Silent (SNP) | VAF 168/427 reads (39%) | called by muse, mutect2, varscan2
- MPC1L | c.306C>T p.L102= | Silent (SNP) | VAF 113/113 reads (100%) | called by muse, mutect2, varscan2
- MTOR | c.5229G>T p.L1743= | Silent (SNP) | VAF 118/291 reads (41%) | called by muse, mutect2, varscan2
- MYH2 | c.4314G>A p.V1438= | Silent (SNP) | VAF 272/272 reads (100%) | called by muse, mutect2, varscan2
- MYO18B | c.5985G>T p.R1995= | Silent (SNP) | VAF 140/140 reads (100%) | called by muse, mutect2, varscan2
- NKX2-2 | c.175C>T p.L59= | Silent (SNP) | VAF 165/516 reads (32%) | called by muse, mutect2, varscan2
- NMUR1 | c.432C>A p.V144= | Silent (SNP) | VAF 26/734 reads (4%) | catalogued as COSV59403873, COSV59404163; called by muse, mutect2
- NOBOX | c.183C>T p.S61= | Silent (SNP) | VAF 136/375 reads (36%) | catalogued as rs762791118; called by muse, mutect2, varscan2
- NOTUM | c.612C>T p.G204= | Silent (SNP) | VAF 106/524 reads (20%) | catalogued as rs757099171, COSV101293741; called by muse, varscan2
- NRAP | c.3873C>A p.L1291= (on ENST00000359988 / NM_001322945.2; = p.L1256= on NM_006175.4) | Silent (SNP) | VAF 62/241 reads (26%) | called by muse, mutect2, varscan2
- NTRK3 | c.279G>T p.T93= | Silent (SNP) | VAF 338/444 reads (76%) | catalogued as COSV58121730; called by muse, mutect2, varscan2
- OR10J3 | c.642G>T p.L214= | Silent (SNP) | VAF 161/414 reads (39%) | catalogued as COSV59955656; called by muse, mutect2, varscan2
- OR10J5 | c.324C>A p.A108= | Silent (SNP) | VAF 232/380 reads (61%) | called by muse, mutect2, varscan2
- OR2A1 | c.225C>T p.N75= | Silent (SNP) | VAF 91/1790 reads (5%) | catalogued as rs757217770; called by muse, mutect2
- OR2T2 | c.285C>T p.F95= | Silent (SNP) | VAF 162/1674 reads (10%) | catalogued as rs1237183660, COSV61618100; called by muse, mutect2
- OR52L1 | c.795C>T p.V265= | Silent (SNP) | VAF 166/364 reads (46%) | called by muse, mutect2, varscan2
- OR56A5 | c.519A>T p.A173= | Silent (SNP) | VAF 160/374 reads (43%) | called by muse, mutect2
- OR5B17 | c.939C>A p.V313= | Silent (SNP) | VAF 37/227 reads (16%) | catalogued as rs942161606, COSV100641927; called by muse, mutect2, varscan2
- PAX1 | c.189C>T p.G63= | Silent (SNP) | VAF 105/307 reads (34%) | called by muse, mutect2, varscan2
- PCARE | c.2619C>T p.T873= | Silent (SNP) | VAF 415/539 reads (77%) | called by muse, mutect2, varscan2
- PCDHB8 | c.2052C>T p.A684= | Silent (SNP) | VAF 177/485 reads (36%) | catalogued as rs373119743, COSV50831214; called by muse, mutect2, varscan2
- PDZD4 | c.1893C>T p.D631= | Silent (SNP) | VAF 22/651 reads (3%) | catalogued as COSV51251460; called by muse, mutect2
- PIAS4 | c.726C>T p.P242= | Silent (SNP) | VAF 90/304 reads (30%) | called by muse, mutect2, varscan2
- PIEZO2 | c.5826G>A p.T1942= | Silent (SNP) | VAF 212/534 reads (40%) | catalogued as rs890957793, COSV53288456; called by muse, varscan2
- POTEE | c.6G>T p.V2= | Silent (SNP) | VAF 86/151 reads (57%) | called by muse, mutect2, varscan2
- PRAMEF18 | c.66C>A p.A22= | Silent (SNP) | VAF 104/926 reads (11%) | called by muse, varscan2
- PRDM2 | c.5061A>T p.R1687= | Silent (SNP) | VAF 190/331 reads (57%) | called by muse, mutect2, varscan2
- PREX1 | c.2704A>C p.R902= | Silent (SNP) | VAF 69/577 reads (12%) | called by muse, mutect2, varscan2
- PRF1 | c.525G>A p.E175= | Silent (SNP) | VAF 127/191 reads (66%) | called by muse, mutect2, varscan2
- PRR23C | c.78C>T p.A26= | Silent (SNP) | VAF 105/548 reads (19%) | called by muse, mutect2, varscan2
- PRRC2B | c.5733T>A p.S1911= | Silent (SNP) | VAF 183/278 reads (66%) | called by muse, mutect2, varscan2
- PTBP2 | c.1326C>G p.S442= (on ENST00000426398 / NM_001300986.2; = p.S434= on NM_021190.4) | Silent (SNP) | VAF 154/339 reads (45%) | called by muse, mutect2, varscan2
- PTPN20 | c.597C>G p.R199= | Silent (SNP) | VAF 38/349 reads (11%) | called by muse, mutect2, varscan2
- PTPRK | c.1476C>T p.P492= | Silent (SNP) | VAF 20/304 reads (7%) | catalogued as rs371808772; called by muse, mutect2
- RASA2 | c.2073A>T p.V691= | Silent (SNP) | VAF 182/519 reads (35%) | called by muse, mutect2, varscan2
- RFPL4AL1 | c.189C>G p.P63= | Silent (SNP) | VAF 66/82 reads (80%) | called by mutect2, varscan2
- RPH3A | c.837C>G p.A279= (on ENST00000389385 / NM_001143854.2; = p.A275= on NM_014954.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 244/390 reads (63%) | called by muse, varscan2
- SAV1 | c.85C>T p.L29= | Silent (SNP) | VAF 134/280 reads (48%) | called by muse, mutect2, varscan2
- SCART1 | c.861G>A p.S287= | Silent (SNP) | VAF 184/509 reads (36%) | catalogued as rs764816021; called by muse, mutect2, varscan2
- SEMA4F | c.642G>T p.R214= | Silent (SNP) | VAF 42/311 reads (14%) | catalogued as rs146486166; called by muse, mutect2, varscan2
- SENP7 | c.2037T>C p.C679= | Silent (SNP) | VAF 228/430 reads (53%) | called by muse, mutect2, varscan2
- SEPTIN3 | c.261C>T p.I87= | Silent (SNP) | VAF 204/406 reads (50%) | catalogued as rs995227275; called by muse, mutect2, varscan2
- SIGLEC5 | c.360G>C p.V120= | Silent (SNP) | VAF 144/461 reads (31%) | called by muse, varscan2
- SLC3A1 | c.306G>T p.A102= | Silent (SNP) | VAF 98/607 reads (16%) | called by muse, mutect2, varscan2
- SMC4 | c.3618T>G p.A1206= | Silent (SNP) | VAF 231/667 reads (35%) | called by muse, mutect2, varscan2
- SMKR1 | c.87C>A p.P29= | Silent (SNP) | VAF 121/642 reads (19%) | called by muse, mutect2, varscan2
- SNTB2 | c.162C>T p.A54= | Silent (SNP) | VAF 236/238 reads (99%) | catalogued as rs1258437153; called by muse, mutect2, varscan2
- SPG7 | c.1005A>G p.P335= (on ENST00000268704; = p.P342= on NM_003119.4) | Silent (SNP) | VAF 324/327 reads (99%) | catalogued as rs751449066; ClinVar: likely benign; called by muse, mutect2, varscan2
- SUGP2 | c.849G>T p.G283= | Silent (SNP) | VAF 115/775 reads (15%) | called by muse, mutect2, varscan2
- TBX22 | c.630C>A p.G210= | Silent (SNP) | VAF 244/244 reads (100%) | called by muse, mutect2, varscan2
- TIMELESS | c.339G>A p.V113= | Silent (SNP) | VAF 180/317 reads (57%) | called by muse, mutect2, varscan2
- TMEM104 | c.540C>T p.G180= | Silent (SNP) | VAF 67/407 reads (16%) | called by muse, mutect2, varscan2
- TMEM221 | c.135C>G p.R45= | Silent (SNP) | VAF 221/308 reads (72%) | called by muse, mutect2, varscan2
- TMEM63B | c.1965G>A p.K655= | Silent (SNP) | VAF 115/457 reads (25%) | called by muse, mutect2, varscan2
- TOR4A | c.354C>T p.R118= | Silent (SNP) | VAF 214/333 reads (64%) | called by muse, mutect2, varscan2
- TRANK1 | c.6606A>G p.L2202= | Silent (SNP) | VAF 69/358 reads (19%) | called by muse, mutect2, varscan2
- TRAV23DV6 | c.171G>A p.A57= | Silent (SNP) | VAF 201/393 reads (51%) | catalogued as rs1259538831; called by muse, mutect2, varscan2
- TRIM64 | c.1053C>T p.N351= | Silent (SNP) | VAF 278/303 reads (92%) | called by muse, mutect2, varscan2
- TRPC5 | c.1443C>G p.L481= | Silent (SNP) | VAF 219/376 reads (58%) | catalogued as rs771289425; called by muse, mutect2, varscan2
- UBQLN3 | c.1113G>A p.Q371= | Silent (SNP) | VAF 196/461 reads (43%) | called by muse, mutect2, varscan2
- VEGFC | c.438C>A p.V146= | Silent (SNP) | VAF 141/296 reads (48%) | catalogued as rs563624007, COSV54599762; called by muse, mutect2, varscan2
- ZFHX4 | c.5064A>G p.P1688= | Silent (SNP) | VAF 80/625 reads (13%) | called by muse, mutect2, varscan2
- ZNF217 | c.1221G>T p.S407= | Silent (SNP) | VAF 243/804 reads (30%) | catalogued as COSV56600148; called by muse, mutect2, varscan2
- ZNF385A | c.603C>G p.L201= (on ENST00000338010 / NM_001130967.3; = p.L181= on NM_015481.3) | Silent (SNP) | VAF 258/443 reads (58%) | catalogued as COSV100567046; called by muse, mutect2, varscan2
- ZNF655 | c.234C>T p.H78= | Silent (SNP) | VAF 68/426 reads (16%) | catalogued as rs1187729401; called by muse, mutect2, varscan2
- ZP4 | c.93G>T p.V31= | Silent (SNP) | VAF 90/566 reads (16%) | catalogued as COSV100850463; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73823186 C>A | 5'Flank (SNP) | VAF 232/233 reads (100%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73851409 C>A | 3'Flank (SNP) | VAF 207/207 reads (100%) | called by muse, mutect2, varscan2
- ATAD3B | c.*367G>T | 3'UTR (SNP) | VAF 217/464 reads (47%) | called by muse, mutect2, varscan2
- CFAP99 | chr4:2459214 G>A | 5'Flank (SNP) | VAF 123/685 reads (18%) | catalogued as rs1056764182; called by muse, mutect2, varscan2
- CUL7 | c.-210A>G | 5'UTR (SNP) | VAF 277/725 reads (38%) | catalogued as rs996678944; called by muse, mutect2, varscan2
- DLEU1 | n.1079G>A | RNA (SNP) | VAF 109/352 reads (31%) | called by muse, mutect2, varscan2
- DNAH14 | c.1825+670T>C | Intron (SNP) | VAF 9/110 reads (8%) | called by muse, mutect2
- DNAH2 | c.1170+819G>A | Intron (SNP) | VAF 90/271 reads (33%) | catalogued as rs757053437; called by muse, mutect2, varscan2
- DOCK8 | c.53+45G>C | Intron (SNP) | VAF 272/582 reads (47%) | catalogued as rs758218649, COSV101213681; called by muse, mutect2
- DST | c.4296+3890G>A | Intron (SNP) | VAF 474/1112 reads (43%) | catalogued as rs1174136904; called by muse, mutect2, varscan2
- ENDOV | c.586-26G>C | Intron (SNP) | VAF 204/592 reads (34%) | catalogued as COSV60496934; called by muse, mutect2, varscan2
- HEPACAM2 | c.*268A>T | 3'UTR (SNP) | VAF 72/353 reads (20%) | called by muse, mutect2, varscan2
- KCNIP4 | c.62-101180A>T | Intron (SNP) | VAF 153/448 reads (34%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-31231T>A | Intron (SNP) | VAF 39/230 reads (17%) | called by muse, mutect2, varscan2
- LRRFIP1 | c.154-1738A>G | Intron (SNP) | VAF 221/376 reads (59%) | catalogued as COSV55251871; called by muse, mutect2, varscan2
- NPAP1L | n.359G>A | RNA (SNP) | VAF 42/178 reads (24%) | called by muse, mutect2, varscan2
- NPAP1L | n.156A>T | RNA (SNP) | VAF 52/151 reads (34%) | catalogued as rs965600602; called by muse, mutect2, varscan2
- NR2F2 | c.-1073A>G | 5'UTR (SNP) | VAF 303/389 reads (78%) | called by muse, mutect2, varscan2
- NRXN2 | c.3403+5456G>A | Intron (SNP) | VAF 118/362 reads (33%) | called by muse, mutect2, varscan2
- PCSK5 | c.2626+3513A>G | Intron (SNP) | VAF 112/352 reads (32%) | called by muse, mutect2, varscan2
- PFDN4 | c.*459T>C | 3'UTR (SNP) | VAF 53/147 reads (36%) | called by muse, mutect2, varscan2
- REG3A | c.*121C>A | 3'UTR (SNP) | VAF 325/565 reads (58%) | called by muse, mutect2, varscan2
- REXO1L1P | n.858G>C | RNA (SNP) | VAF 65/1482 reads (4%) | called by muse, mutect2
- SLAMF8 | chr1:159837953 C>A | 3'Flank (SNP) | VAF 195/474 reads (41%) | called by muse, mutect2, varscan2
- SLC25A38 | c.69+896T>C | Intron (SNP) | VAF 219/306 reads (72%) | catalogued as rs555828444; called by muse, mutect2, varscan2
- USH1C | c.1284+7588C>T | Intron (SNP) | VAF 70/292 reads (24%) | catalogued as rs778703128, CM1211757; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF619 | c.80+248G>T | Intron (SNP) | VAF 249/321 reads (78%) | called by muse, mutect2, varscan2
- ZNF836 | c.142+27A>G | Intron (SNP) | VAF 189/509 reads (37%) | called by muse, mutect2, varscan2
